Somatic mutation profile of tumor specimen TCGA-HT-7881-01A (aliquot TCGA-HT-7881-01A-11D-2395-08) from TCGA case TCGA-HT-7881, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 38.8 years (14,171 days).
Specimen TCGA-HT-7881-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46985016-b0c9-4fc2-8204-01e661e260af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7881-10A (Blood Derived Normal), aliquot TCGA-HT-7881-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1d5a10f-736e-4a58-bd1b-cdc8835fe476

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 17/127 reads (13%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AHR | c.1690A>T p.N564Y | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV54125446; called by muse, mutect2, varscan2
- C10orf82 | c.454T>C p.Y152H | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs201735695; called by muse, mutect2
- CDH12 | c.269A>G p.K90R | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.312); catalogued as COSV66433181; called by muse, mutect2
- PLCL1 | c.2438C>T p.T813M | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748546401, COSV70827442; called by muse, mutect2, varscan2
- ZBTB20 | c.734C>G p.S245W (on ENST00000474710 / NM_001164342.2; = p.S172W on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); catalogued as COSV61862290, COSV61865417; called by muse, mutect2, varscan2
- ZNF24 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 8/160 reads (5%) | catalogued as rs1474538878; called by muse, mutect2
- ZNF425 | c.1919G>A p.C640Y | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749767822, COSV65202202; called by muse, mutect2
- ARHGAP33 | c.141T>G p.A47= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV99139409; called by muse, mutect2
- HSPD1 | c.1515T>A p.A505= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV61445582; called by muse, mutect2
